Somatic mutation profile of tumor specimen MP2PRT-PAVSVG-TBP1-A (aliquot MP2PRT-PAVSVG-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVSVG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,211 days).
Specimen MP2PRT-PAVSVG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9a0a192-4fb1-47bb-ab49-0bc19e115645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSVG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSVG-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b286b16e-14a1-4ca5-ae9d-4c36c7957373

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/417 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as rs1473690516; called by muse, mutect2
- CALHM6 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 34/765 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- COL6A6 | c.1548C>T p.G516= | Silent (SNP) | VAF 36/579 reads (6%) | catalogued as rs368134547; called by muse, mutect2
- IGKV5-2 | c.222C>A p.L74= | Silent (SNP) | VAF 31/385 reads (8%) | called by muse, mutect2
